TCGA case TCGA-30-1860 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Harvard. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/563853a2-9ac2-48be-adf3-1e547ee2b274

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 58 years; Vital status: Dead; Days to death: 1,366 days (3.7 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 58.6 years (21,406 days); Year of diagnosis: 2002; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: G3; Prior treatment: No.
   Pathology details: Lymphatic invasion present: No; Residual tumor measurement: >20 mm; Vascular invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 22 days; Days to treatment end: 207 days; Number of cycles: 7; Treatment dose: 5 AUC; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 22 days; Days to treatment end: 207 days; Number of cycles: 7; Treatment dose: 175 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Initial disease status: Recurrent Disease; Days to treatment start: 413 days (1.1 years); Days to treatment end: 561 days (1.5 years); Number of cycles: 3; Treatment dose: 40 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Progressive Disease; Days to treatment start: 744 days (2.0 years); Days to treatment end: 915 days (2.5 years); Number of cycles: 6; Treatment dose: 5 AUC; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Initial disease status: Progressive Disease; Days to treatment start: 744 days (2.0 years); Days to treatment end: 915 days (2.5 years); Number of cycles: 6; Treatment dose: 750 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Initial disease status: Progressive Disease; Days to treatment start: 915 days (2.5 years); Days to treatment end: 957 days (2.6 years); Number of cycles: 6; Treatment dose: 4 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Progressive Disease; Days to treatment start: 994 days (2.7 years); Days to treatment end: 1,069 days (2.9 years); Number of cycles: 12; Treatment dose: 70 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Progressive Disease; Days to treatment start: 1,006 days (2.8 years); Days to treatment end: 1,055 days (2.9 years); Treatment dose: 4,500 cGy; Number of fractions: 25; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 1,191 days (3.3 years); Days to treatment end: 1,246 days (3.4 years); Treatment dose: 10 mg/kg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Vinorelbine Tartrate; Initial disease status: Progressive Disease; Days to treatment start: 1,191 days (3.3 years); Days to treatment end: 1,246 days (3.4 years); Number of cycles: 5; Treatment dose: 15 mg/m2; Route of administration: Intravenous.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 59.7 years (21,803 days); Days to diagnosis: 397 days (1.1 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 974 days (2.7 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.

Follow-up (3 entries)
- Day 397 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 397 days (1.1 years); Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 1,366 days (3.7 years); Disease response: With Tumor.
- Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Evidence of recurrence type: Convincing Image Source; Timepoint: Post Initial Treatment.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-30-1860-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.5; Intermediate dimension: 0.4; Shortest dimension: 0.3.
  Slide TCGA-30-1860-01A-01-BS1: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 5.
  Slide TCGA-30-1860-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10.
- Sample TCGA-30-1860-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Lymphovascular invasion indicator: No.
- Drug treatment 1: Therapy regimen: Progression.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Pharmaceutical therapy drug name: Taxol; Therapy regimen: Progression.
- Drug treatment 4: Pharmaceutical therapy drug name: Doxil.
- Drug treatment 6: Pharmaceutical therapy drug name: Navelbine; Therapy regimen: Progression.
- Drug treatment 9: Pharmaceutical therapy drug name: Avastin; Therapy regimen: Progression.
- Drug treatment 9, Route of administrations: Route of administration: PO.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,366 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,366 days; disease-free interval: event (new tumor event after initially disease-free), 397 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 397 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-30-1860-01): tumor purity 0.79, ploidy 1.75, whole-genome doublings 0 (call status: legacy_call).
